CCDI case PBCLXY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/41af5210-1137-4dd4-ada6-bb0347071ac0

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 13.4 years (4,887 days).

Biospecimens (3 samples)
- Sample 0DVZ0L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ0X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVZ1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
